CCDI case PBBPMR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/de7ce5f9-1cc0-433e-b5f3-1b80fd3ef7b6

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Lymph nodes of inguinal region or leg; Age at diagnosis: 2.6 years (942 days).

Biospecimens (3 samples)
- Sample 0DFBLB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFBLE: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFBLP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
